Gene-level copy-number profile of tumor specimen TCGA-CQ-A4C6-01A from TCGA case TCGA-CQ-A4C6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 63.5 years (23,205 days).
Specimen TCGA-CQ-A4C6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0005feff-0d0e-44df-b4cb-df334ebc1c1b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-A4C6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ea5c49a5-2c79-4c14-be34-d148fb6e50ca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 3,846; copy number 3: 5,004; copy number 4: 39,219; copy number 5: 1,552; copy number 6: 776; copy number 7: 1,988; copy number 8: 5,791; copy number 9: 1,534; copy number 12: 19; copy number 15: 3; copy number 17: 71; copy number 26: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-A4C6-01A-11D-A253-01): tumor purity 0.36, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,634 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9 (broad region; genes not listed).
- chr11:69,147,228–72,139,892, 97 genes, copy number 12–26 (broad region; genes not listed).
- chr18:22,347,846–22,419,294, 3 genes, copy number 15: AC027449.1, CTAGE1, ATP7BP1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
